Gene-level copy-number profile of tumor specimen TCGA-86-8056-01A from TCGA case TCGA-86-8056, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 64.0 years (23,369 days).
Specimen TCGA-86-8056-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.28b378a6-fbd7-4980-b9a0-cd3841259b7e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8056-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/419866f5-b774-44f1-bbf3-82f8ec4a97f5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,895; copy number 2: 51,465; copy number 3: 1,568; copy number 4: 307; copy number 5: 391; copy number 6: 192.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8056-01A-11D-2237-01): tumor purity 0.37, ploidy 3.87, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 583 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,782,671–153,003,856, 182 genes, copy number 5 (broad region; genes not listed).
- chr1:155,148,544–164,980,137, 368 genes, copy number 5–6 (broad region; genes not listed).
- chr1:165,210,627–165,213,090, 1 gene, copy number 5: LMX1A-AS2.
- chr5:65,722,205–65,871,725, 2 genes, copy number 6: NLN, AC008958.1.
- chr5:168,085,329–168,579,368, 10 genes, copy number 6 (within-gene range 1–6): AC011369.1, AC011369.2, CTB-178M22.2, WWC1, RARS1, FBLL1, PANK3, SLC2A3P1, MIR103A1, MIR103B1.
- chr5:169,861,303–171,300,015, 20 genes, copy number 5 (within-gene range 2–5): INSYN2B, MIR378E, FOXI1, KRT18P41, LINC01187, C5orf58, LCP2, AC034199.2, LINC01366, AC034199.1, KCNIP1, KCNMB1, KCNIP1-OT1, AC008619.1, KCNIP1-AS1, AC008514.1, GABRP, RANBP17, RN7SL623P, AC008514.2.

Autosomal genes at a single copy (total copy number 1): 5,895. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
